FM case AD14781 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Epithelial Neoplasms, NOS; Primary site: Breast.
https://portal.gdc.cancer.gov/cases/243e1f16-5561-467e-8c5c-9261dece1d05

Female, 52.6 years: Carcinoma, NOS (ICD-O-3 8010/3) of the breast; metastasis biopsied or resected from the specified parts of peritoneum. Tumor nuclei on the sequenced sample's slide: 25% (pathologist estimate recorded by GDC). Sample type: Metastatic.
